Surgical pathology report (de-identified scan), TCGA case TCGA-K4-AAQO, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-AAQO-01A (Primary Tumor).

[page 1 of 6]
Gender

M

Date Of Birth

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Received

Time Reported

Order Number

Ordering Provider

Status

Correction to results

Results

Correction

Source of Specimen

- A. LEFT DISTAL URETER FS-
- B. RIGHT DISTAL URETER FS-
- C. LEFT OBTURATOR LYMPH NODES-
- D. LEFT EXTERNAL ILIAC LYMPH NODES-
- E. LEFT INTERNAL & COMMON ILIAC LYMPH NODES-
- F. RIGHT OBTURATOR LYMPH NODES-
- G. RIGHT EXTERNAL ILIAC LYMPH NODES-
- H. RIGHT INTERNAL & COMMON ILIAC LYMPH NODES-
- I. BLADDER & PROSTATE-
- J. HERNIA SAC

FINAL DIAGNOSIS:

- A. LEFT DISTAL URETER FS-
NO CARCINOMA SEEN.
- B. RIGHT DISTAL URETER FS-
NO CARCINOMA SEEN.
- C. LEFT OBTURATOR LYMPH NODES-
TWO LYMPH NODES, NO MALIGNANCY SEEN.
- D. LEFT EXTERNAL ILIAC LYMPH NODES-
FOUR LYMPH NODES, NO MALIGNANCY SEEN.
- E. LEFT INTERNAL & COMMON ILIAC LYMPH NODES-
SEVEN LYMPH NODES, NO MALIGNANCY SEEN.
- F. RIGHT OBTURATOR LYMPH NODES-
THREE LYMPH NODES, NO MALIGNANCY SEEN.
- G. RIGHT EXTERNAL ILIAC LYMPH NODES-
TWO LYMPH NODES, NO MALIGNANCY SEEN.
- H. RIGHT INTERNAL & COMMON ILIAC LYMPH NODES-
FOUR LYMPH NODES, NO MALIGNANCY SEEN.

ICD-O-3
Carcinoma, urothelial NOS 8/20/13
Site: Bladder, anterior wall C67.3
JF 6/13/14

Prepared for

[page 2 of 6]
I. BLADDER & PROSTATE-
INVASIVE CARCINOMA, HIGH GRADE.

TUMOR SITE: ANTERIOR WALL, URINARY BLADDER.

HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: IS NOT PRESENT.

GLANDULAR DIFFERENTIATION: IS PRESENT, FOCAL.

TUMOR SIZE: 5.0 CM.

HISTOLOGIC GRADE: 2-3/3.

EXTRAVESICULAR MASS: NOT PRESENT.

SPECIMEN TYPE: RADICAL CYSTOPROSTATECTOMY.

TNM STAGE: pT3a, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED: 0
NUMBER EXAMINED: 23

LYMPHATIC (SMALL VESSEL) INVASION: IS SEEN.

PERINEURAL INVASION: IS SEEN.

ASSOCIATED EPITHELIAL LESIONS: CHRONIC CYSTITIS.

NO TUMOR SEEN AT URETERAL, URETHRAL AND SOFT TISSUE RESECTION
MARGINS.

ONE PERIVESICAL LYMPH NODE, NEGATIVE FOR MALIGNANCY.

J. HERNIA SAC

CAUTERIZED FIBROADIPOSE TISSUE WITH FOCAL MESOTHELIAL LINING
CONSISTENT WITH HERNIA SAC.

NO MALIGNANCY SEEN.

Signature

(Case signed

Signed Others

Frozen Section

A. LEFT DISTAL URETER, FS: SEGMENT OF URETER WITH FOCAL MILD
ATYPIA. NO INVASIVE CARCINOMA SEEN.

Prepared for

[page 3 of 6]
RIGHT DISTAL URETER, FS: NO CARCINOMA SEEN.
Frozen section performed by

(Frozen Section Signed

Case Clinical Information
BLADDER CANCER

Gross Description

- A. Received in formalin labeled with the patient's name and "left distal ureter-FS" is a yellow/tan tissue measuring 5 x 5 x 1 mm thick. Entirely submitted in A1.
- B. Received in formalin labeled with the patient's name and "right distal ureter-FS" are two yellow/tan tissues. Each measures 3 mm in greatest dimension. Entirely submitted in B1.
- C. Received in formalin labeled with the patient's name and "left obturator lymph nodes" are multiple fragments of finely divided fat measuring 2 x 2 x 2 cm. The dominant lymph node is bisected and totally submitted in C1. A second lymph node is bisected and submitted in C2.
- D. Received in formalin labeled with the patient's name and "left external iliac lymph nodes" are two fat pads measuring 2 x 2 x 2 cm in compact aggregate. No significant induration is encountered. All material is submitted in D1-D3.
- E. Received in formalin labeled with the patient's name and "left internal and common iliac lymph nodes" is a fat pad measuring 5 x 4 x 1.2 cm thick. An area of dominant fatty induration is bisected and submitted in E1-E2; remaining induration in E3.
- F. Received in formalin labeled with the patient's name and "right obturator lymph nodes" is a fat pad measuring 2 x 2 x 2 cm. There are two areas of induration which are bisected and submitted in separate cassettes, F1, F2.
- G. Received in formalin labeled with the patient's name and "right external iliac lymph nodes" is a fat pad measuring 5 x 3 x 1.5 cm. An area of dominant induration is bisected and submitted in G1; remaining subtle induration in G2.
- H. Received in formalin labeled with the patient's name and "right internal and common iliac lymph nodes" is an irregular fragment of fibroadipose tissue measuring 8 x 3.5 x 2 cm thick. A dominant area of induration is bisected and submitted in H1; remaining induration in H2-H3.
- I. Received in formalin labeled with the patient's name and "bladder and prostate" is a specimen so designated, overall measuring 14 cm superior to inferior x 12 cm right to left x 5

[page 4 of 6]
cm anterior to posterior. The specimen is inked blue on the right; black, left. The included prostate measures 3.5 cm superior to inferior x 4 cm right to left x 2.5 cm anterior to posterior. The bladder cavity measures 3 cm superior to inferior x 2 cm right to left x 1.5 cm anterior to posterior. It appears distinctly contracted and is associated with a conspicuous transmural mass involving the entire anterior wall of the bladder measuring overall 5 x 3 x up to 1.5 cm thick. The mass projects along the posterior bladder wall for 3.5 cm on the right and left. The right and left seminal vesicles on palpation measure 1.8 x 1 x 0.8 cm and 2 x 1.2 x 0.8 cm in greatest dimensions. The ureteral stubs are deeply retracted, but are not sampled at this time since they are reflected in "A" and "B". The posterior bladder mucosa appears unremarkable. Grossly, the anterior surgical resection margin appears free of tumor for a minimum of 0.5 cm grossly. The section code is as follows: I1=left seminal vesicle and shave of left vas; I2=right seminal vesicle and shave of right vas; I3=shave of distal prostate; I4-I6=mid-posterior prostate; I7-I9=superior posterior prostate; I10, I11=sagittal plane sections of left anterior bladder wall; I12=sagittal plane sections of right anterior bladder wall in relationship to inked anterior margin; I13-I15=additional sections of left lateral bladder wall proceeding inferior to superior; and I16-I18=right lateral bladder wall and additional representative sections proceeding inferior to superior.

J. Received in formalin labeled with the patient's name and "hernia sac" is a fibromembranous specimen measuring 3 x 1.5 x 1 cm with an area of nodularity at one end. Entirely submitted in J1.

Physicians

Signed Supplemental

I. The prostate shows foci of acute and chronic inflammation. No malignancy is seen.

(Supplemental Report Signed

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.1
H&E X1

Prepared for

[page 5 of 6]
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1 A RECUTS
F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
G. AA ROUTINE H&E X1 BLOCK.1
H&E X1
G. AA ROUTINE H&E X1 BLOCK.2
H&E X1
H. AA ROUTINE H&E X1 BLOCK.1
H&E X1
H. AA ROUTINE H&E X1 BLOCK.2
H&E X1
H. AA ROUTINE H&E X1 BLOCK.3
H&E X1 AA RECUT
I. AA ROUTINE H&E X1 BLOCK.1
H&E X1
I. AA ROUTINE H&E X1 BLOCK.2
H&E X1
I. AA ROUTINE H&E X1 BLOCK.3
H&E X1
I. AA ROUTINE H&E X1 BLOCK.4
H&E X1
I. AA ROUTINE H&E X1 BLOCK.5
H&E X1
I. AA ROUTINE H&E X1 BLOCK.6
H&E X1
I. AA ROUTINE H&E X1 BLOCK.7
H&E X1
I. AA ROUTINE H&E X1 BLOCK.8
H&E X1
I. AA ROUTINE H&E X1 BLOCK.9
H&E X1
I. AA ROUTINE H&E X1 BLOCK.10
H&E X1

[page 6 of 6]
I. AA ROUTINE H&E X1 BLOCK.11
H&E X1

I. AA ROUTINE H&E X1 BLOCK.12
H&E X1 AA RECUT

I. AA ROUTINE H&E X1 BLOCK.13
H&E X1

I. AA ROUTINE H&E X1 BLOCK.14
H&E X1

I. AA ROUTINE H&E X1 BLOCK.15
H&E X1

I. AA ROUTINE H&E X1 BLOCK.16
H&E X1

I. AA ROUTINE H&E X1 BLOCK.17
H&E X1

I. AA ROUTINE H&E X1 BLOCK.18
H&E X1

J. AA ROUTINE H&E X1 BLOCK
H&E X1 A RECUTS

Prepared for

Source: NCI Genomic Data Commons file 0ac541fd-99e6-435d-b509-0369a1ae71d8 (TCGA-K4-AAQO.30D1A38A-F0C3-46F6-BDB9-6C629E6E517E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).